Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2MI, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2MI-06A (Metastatic).

[page 1 of 2]
PathNet History Upload External
Client

DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to: N/A

ARCHIVAL HISTOPATHOLOGY REPORT

Accession Number:

Collected Date:

HISTORICAL REQUEST DETAILS

CLINICAL NOTES

Metastatic melanoma Rt axilla - apical node in separate container.

SPECIMEN INFORMATION

Histopath.

MACROSCOPIC DESCRIPTION

Two specimens received.

I. "Right axillary contents". A piece of fatty tissue, 150 x 145 x 50mm with an attached portion of skeletal muscle 70 x 60 x 45mm. The specimen was examined for lymph nodes. Sectioning reveals two adjacent well circumscribed firm white tumour nodules 47 x 40 x 37mm and 45 x 30 x 30mm. Both of the nodules are approximately 4mm from the nearest surgical margin. There is also a firm nodule up to 38mm in diameter.

A-C. Each one section through three large nodules (from largest to smallest).

D-H. Each one node in two pieces.

J. 3 nodes.

K-N. Each 5 nodes.

II. "Apical node right axilla". Two pieces of fatty tissue, 30 x 12 x 10mm and 20 x 15 x 5mm which were examined to reveal two lymph nodes 4 and 9mm across. Both embedded in one block.

MICROSCOPIC REPORT

I. "Right axillary contents". The 3 large nodules show metastatic malignant melanoma with focal pigment formation. No evidence of malignancy seen in the remaining lymph nodes.

II. "Apical node right axilla". No evidence of malignancy seen in either lymph node.

Electronic signature

Verified by:

ICD-0-3
Melanoma, NOS 8720/3
Site: lymph node, axillary
C 77.3
hw 8/24/11

Case is (-circled):		

hw 8/24/11

Printed

[page 2 of 2]
Requested by: N/A

MRN/Name:

Location:

Accession:

ARCHIVAL HISTOPATHOLOGY REPORT

Accession Number:

Collected Date:

SUMMARY / KEY WORDS

Lymph node, axillary - malignant melanoma, metastatic.

Haematopathology resection

Source: NCI Genomic Data Commons file c150bf93-2ff1-4494-a44e-df941c1a9cad (TCGA-EE-A2MI.B9B99EA2-EB57-4C49-9BB3-35F3D9E7CF07.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).